Somatic mutation profile of tumor specimen TCGA-F7-A50J-01A (aliquot TCGA-F7-A50J-01A-21D-A28R-08) from TCGA case TCGA-F7-A50J, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 67.8 years (24,758 days).
Specimen TCGA-F7-A50J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 266b306c-fe12-4452-b9a2-e340ed3a475b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A50J-10A (Blood Derived Normal), aliquot TCGA-F7-A50J-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cdb3ccf-b3da-419c-9131-4a28d8488ccc

The open-access MAF lists 182 somatic variants for this specimen: 127 protein-altering or splice-affecting, 52 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 106, Silent 52, Nonsense Mutation 13, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, In Frame Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3203dup p.N1068Kfs*5 | Frame Shift Ins (INS) | VAF 22/79 reads (28%) | catalogued as rs587776802; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.7419A>T p.E2473D | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as COSV101447028; called by muse, mutect2, varscan2
- ABCG4 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 12/155 reads (8%) | catalogued as COSV100266889; called by muse, mutect2
- ACTN3 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs1201348087, COSV101557848; called by muse, mutect2, varscan2
- ACVR1C | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1433923561, COSV54644275; called by muse, mutect2, varscan2
- ADAMTS3 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as rs145300703; called by muse, mutect2, varscan2
- ADGRF4 | c.245del p.K82Sfs*29 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | catalogued as rs764604854; called by mutect2, varscan2
- AGTPBP1 | c.1633C>G p.Q545E (on ENST00000357081 / NM_001330701.2; = p.Q505E on NM_015239.2) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100429944; called by muse, mutect2, varscan2
- AHNAK | c.8818G>C p.E2940Q | Missense Mutation (SNP) | VAF 56/324 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV99948353; called by muse, mutect2, varscan2
- ALK | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV101202344; called by muse, mutect2, varscan2
- AMPD3 | c.311C>T p.P104L (on ENST00000396553 / NM_001025389.2; = p.P113L on NM_000480.3) | Missense Mutation (SNP) | VAF 38/391 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs770661067, COSV67330791; called by muse, mutect2
- ANO9 | c.1130C>A p.A377D | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100241076; called by muse, mutect2
- AP001781.2 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV99500055; called by muse, varscan2
- ARHGEF1 | c.1652G>A p.R551H | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV61528722; called by muse, mutect2, varscan2
- ASAP2 | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99856464; called by muse, mutect2
- ASB3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99712233; called by muse, mutect2, varscan2
- ASCC3 | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1449848026, COSV61226294; called by muse, mutect2
- ATRNL1 | c.3656T>A p.I1219N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV100371717; called by muse, mutect2, varscan2
- BCAP31 | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100798960; called by muse, mutect2, varscan2
- BIRC6 | c.2357C>A p.S786* | Nonsense Mutation (SNP) | VAF 14/73 reads (19%) | catalogued as COSV70201858; called by muse, mutect2, varscan2
- BRCA1 | c.5210G>C p.R1737T | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV100524650; called by muse, mutect2, varscan2
- CCDC178 | c.2176G>C p.E726Q (on ENST00000383096 / NM_001105528.3; = p.E688Q on NM_198995.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.546); catalogued as COSV100285538; called by muse, mutect2
- CCNJ | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs778391284, COSV99796294; called by muse, mutect2, varscan2
- CDH11 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.099); catalogued as rs199720066, COSV51769154; called by muse, mutect2, varscan2
- CDH7 | c.1355T>A p.V452D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100542760; called by muse, mutect2, varscan2
- CDK10 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367799151; called by muse, mutect2, varscan2
- CMIP | c.1325G>C p.S442T (on ENST00000537098 / NM_198390.2; = p.S348T on NM_030629.3) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV101220938; called by mutect2, varscan2
- COL19A1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs574363456, COSV100506804; called by muse, mutect2
- CPNE8 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.314); catalogued as COSV100504743; called by muse, mutect2, varscan2
- CRAT | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100534124; called by muse, mutect2, varscan2
- CTTN | c.531C>A p.D177E | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.923); catalogued as rs1160779724, COSV100097999; called by muse, mutect2
- DDX11 | c.2686G>A p.V896I (on ENST00000545668 / NM_152438.2; = p.K847= on NM_004399.3) | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99299924; called by muse, mutect2, varscan2
- DNAH5 | c.6548G>A p.R2183H | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749422941, COSV54225165, COSV99451566; called by muse, mutect2, varscan2
- DNAH6 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.286); catalogued as rs145235960; called by muse, mutect2, varscan2
- DSEL | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100025860; called by muse, mutect2, varscan2
- DUSP18 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.109); catalogued as COSV100588843; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2161G>T p.E721* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | catalogued as rs1274420476, COSV100668702; called by muse, mutect2
- EML3 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542275752, COSV99605935; called by muse, mutect2, varscan2
- ENOX2 | c.1226C>G p.S409* (on ENST00000338144 / NM_001382520.1; = p.S380* on NM_006375.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | catalogued as COSV100584340; called by muse, mutect2, varscan2
- ERCC6 | c.2256G>C p.M752I | Missense Mutation (SNP) | VAF 19/180 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV100876009; called by muse, mutect2, varscan2
- F8 | c.1694G>C p.G565A | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM141473, COSV100811657; called by muse, mutect2, varscan2
- FAAH2 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100887376; called by muse, mutect2, varscan2
- FAM111B | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100639318; called by muse, mutect2, varscan2
- FAM47A | c.754C>G p.P252A | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.494); catalogued as COSV100649974, COSV60495260; called by muse, mutect2, varscan2
- FAM47B | c.1418G>C p.G473A | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100264449; called by muse, mutect2
- FASN | c.5404G>A p.E1802K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs764921764, COSV100148038; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGD4 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as rs774787616, COSV99847337; called by muse, mutect2, varscan2
- FLG | c.9464A>T p.Q3155L | Missense Mutation (SNP) | VAF 166/535 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.074); catalogued as COSV100911779; called by muse, mutect2, varscan2
- FOSL1 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100440945; called by muse, mutect2, varscan2
- G6PC3 | c.913C>G p.Q305E | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.275); catalogued as COSV99291296; called by muse, mutect2
- GABRQ | c.206G>C p.R69T | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100941353; called by muse, mutect2
- GCFC2 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs750294560, COSV58079420; called by muse, mutect2, varscan2
- GLI1 | c.815G>T p.W272L | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368789621, COSV99954330; called by muse, mutect2, varscan2
- GLRA3 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as COSV99927795; called by muse, mutect2
- GRIK3 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); catalogued as COSV100902169; called by mutect2, varscan2
- IFT80 | c.1834A>C p.K612Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.077); catalogued as COSV100424910; called by muse, mutect2
- IMMT | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54489021; called by muse, mutect2, varscan2
- IRS4 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.538); catalogued as COSV100929621, COSV64536643; called by muse, mutect2
- IWS1 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1315853780, COSV54866354, COSV54867015, COSV99767403; called by muse, mutect2, varscan2
- KIAA0232 | c.1925C>G p.S642C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV100300880; called by muse, mutect2
- KIF4A | c.2590A>G p.K864E | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100979584; called by muse, mutect2, varscan2
- LRP1 | c.1816G>A p.G606S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99676464; called by muse, mutect2, varscan2
- LRP1 | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54516097, COSV99676468; called by muse, mutect2, varscan2
- MAGEB6B | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV104435545; called by muse, mutect2, varscan2
- METTL25 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99810727; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1175C>A p.T392K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100186942; called by muse, mutect2, varscan2
- MPP2 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV99290555; called by muse, mutect2, varscan2
- MYO18B | c.4001A>C p.K1334T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100124309; called by muse, mutect2, varscan2
- NEBL | c.2657G>C p.S886T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV101009271; called by muse, mutect2, varscan2
- NLRP12 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 49/331 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as rs765948822, COSV100145325, COSV60743430, COSV60753163; called by muse, mutect2, varscan2
- NPVF | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV99760277; called by muse, mutect2, varscan2
- NPY4R | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as rs147108354; called by mutect2, varscan2
- NR3C1 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196433; called by muse, mutect2, varscan2
- NUFIP1 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV100998029; called by muse, mutect2, varscan2
- ODF2 | c.338A>G p.D113G (on ENST00000434106 / NM_153433.2; = p.D89G on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV100654785; called by muse, mutect2, varscan2
- OR6N1 | c.689C>G p.S230* | Nonsense Mutation (SNP) | VAF 23/145 reads (16%) | catalogued as rs768208648, COSV100625221, COSV58649950; called by muse, mutect2, varscan2
- PCDHAC2 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53866027; called by muse, mutect2, varscan2
- PCLO | c.12968C>T p.A4323V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as COSV100434475; called by muse, mutect2, varscan2
- PENK | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.313); catalogued as rs764710411, COSV100152401, COSV59242906; called by muse, mutect2, varscan2
- PHF2 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100823246; called by muse, mutect2, varscan2
- PJA2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV100754479; called by muse, mutect2, varscan2
- PLCB1 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 6/47 reads (13%) | catalogued as rs1172793093, COSV100571587; called by muse, mutect2, varscan2
- PLEC | c.11138_11149del p.G3713_H3717delinsD (on ENST00000322810 / NM_201380.4; = p.G3603_H3607delinsD on NM_000445.5) | In Frame Del (DEL) | VAF 30/278 reads (11%) | catalogued as rs781835064; called by mutect2, pindel, varscan2
- POLR3E | c.1773C>G p.S591R | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV100242240; called by muse, mutect2
- PPP6R3 | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 12/112 reads (11%) | catalogued as rs1565836573, COSV55722231; called by muse, mutect2, varscan2
- PTPN21 | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100162246; called by muse, mutect2, varscan2
- RAD9A | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100334990; called by muse, mutect2
- RASGEF1A | c.1302G>C p.K434N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100988693; called by muse, mutect2, varscan2
- RB1 | c.733C>G p.P245A | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99925584; called by muse, mutect2
- RBBP7 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 15/106 reads (14%) | catalogued as COSV101198303; called by muse, mutect2, varscan2
- RBFOX2 | c.1216G>A p.A406T (on ENST00000438146 / NM_001349995.2; = p.P318= on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs770778072, COSV99455545; called by muse, mutect2, varscan2
- RORA | c.1535C>G p.T512S (on ENST00000335670 / NM_134261.3; = p.T537S on NM_002943.3) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99832870; called by muse, mutect2
- SAMD9 | c.3598G>C p.E1200Q | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV101180307, COSV101180308; called by muse, mutect2, varscan2
- SCAPER | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1326769754, COSV100238862; called by muse, mutect2
- SCUBE2 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 17/246 reads (7%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.756); catalogued as COSV100496802; called by muse, mutect2
- SCYL2 | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.181); catalogued as rs1186599872, COSV100675246; called by muse, mutect2
- SI | c.2891C>T p.T964M | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.438); catalogued as rs369115304, COSV52270430; called by muse, mutect2, varscan2
- SLC13A3 | c.693G>A p.W231* | Nonsense Mutation (SNP) | VAF 13/145 reads (9%) | catalogued as COSV99286892; called by muse, mutect2
- SLC44A3 | c.683C>T p.A228V (on ENST00000271227 / NM_001114106.3; = p.A180V on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99598388; called by muse, mutect2, varscan2
- SLC5A5 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 27/206 reads (13%) | catalogued as rs371248346; called by muse, mutect2, varscan2
- SOST | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1033871363, COSV57012447; called by muse, mutect2, varscan2
- STPG2 | c.1291G>C p.E431Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV54819428, COSV99760280; called by muse, mutect2, varscan2
- STRN4 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99623825; called by muse, mutect2, varscan2
- TENT4A | c.1691G>A p.S564N | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776754058, COSV100049099; called by muse, mutect2, varscan2
- TKTL1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs782095901, COSV54212538; called by muse, mutect2, varscan2
- TLN1 | c.4543C>G p.R1515G | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs758176386, COSV100147946, COSV59205085; called by muse, mutect2, varscan2
- TLR8 | c.1591C>T p.H531Y (on ENST00000218032 / NM_138636.5; = p.H549Y on NM_016610.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV99487135; called by muse, mutect2, varscan2
- TMED3 | c.327C>G p.F109L | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs774406807, COSV100230004; called by muse, mutect2, varscan2
- TMED8 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as rs752927274, COSV99375063; called by muse, mutect2, varscan2
- TMEM31 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100129055; called by muse, mutect2, varscan2
- TRPC5 | c.2371C>T p.R791W | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs138566611, COSV53303947; called by muse, mutect2, varscan2
- TRPV4 | c.1985A>T p.D662V | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV99924835; called by muse, mutect2
- USH2A | c.3970A>G p.T1324A | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100238251; called by muse, mutect2, varscan2
- USH2A | c.1630A>G p.T544A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100231784, COSV56436272; called by muse, mutect2, varscan2
- WDR17 | c.1636G>C p.V546L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.33); catalogued as COSV99707905; called by muse, mutect2, varscan2
- XRCC1 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99486564; called by muse, mutect2, varscan2
- ZMYM3 | c.2112G>T p.E704D | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV100078102; called by muse, mutect2, varscan2
- ZNF43 | c.1591A>G p.T531A | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100731876; called by muse, mutect2, varscan2
- ACACA | c.350C>G p.S117C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ADAM2 | c.1061G>T p.C354F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PARP14 | c.3296_3309del p.N1099Ifs*17 | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel, varscan2
- PCDHGB1 | c.423_427dup p.A143Gfs*7 | Frame Shift Ins (INS) | VAF 14/132 reads (11%) | called by mutect2, pindel
- SACS | c.5908G>T p.G1970* | Nonsense Mutation (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- TRGC1 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC9C | c.15_31del p.E7Gfs*18 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel
- ZFAND3 | c.265_270del p.L89_N90del | In Frame Del (DEL) | VAF 8/42 reads (19%) | called by mutect2, pindel, varscan2
- ZNF17 | c.1182_1185del p.F394Lfs*63 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | called by mutect2, pindel
- AGL | c.3201T>G p.P1067= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99649608; called by muse, mutect2
- AIFM3 | c.1104C>T p.F368= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV100104797; called by muse, mutect2, varscan2
- AKAP17A | c.198G>T p.T66= | Silent (SNP) | VAF 31/300 reads (10%) | catalogued as rs145575351, COSV100002354; called by muse, mutect2
- ARMCX2 | c.579G>A p.V193= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV100168210; called by muse, mutect2, varscan2
- CBFA2T2 | c.831C>G p.L277= | Silent (SNP) | VAF 37/110 reads (34%) | catalogued as COSV100656349, COSV100656428; called by muse, mutect2
- CCDC144A | c.63C>T p.Y21= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV61403024; called by muse, mutect2, varscan2
- CCDC88B | c.711C>T p.L237= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV57265100; called by muse, mutect2
- CELSR2 | c.1567C>T p.L523= | Silent (SNP) | VAF 19/135 reads (14%) | catalogued as COSV99602984, COSV99604315; called by muse, mutect2, varscan2
- CHD2 | c.4407C>T p.F1469= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV101245586; called by muse, mutect2, varscan2
- COL4A1 | c.2316C>T p.I772= | Silent (SNP) | VAF 44/167 reads (26%) | catalogued as rs377593990; called by muse, mutect2, varscan2
- CTC1 | c.3528A>G p.L1176= | Silent (SNP) | VAF 34/96 reads (35%) | catalogued as COSV100236582; called by muse, mutect2, varscan2
- CXorf58 | c.363T>C p.H121= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV101003028; called by muse, mutect2, varscan2
- DAPK2 | c.504G>A p.K168= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs1478644173, COSV99977561; called by muse, mutect2, varscan2
- DCAF6 | c.414G>A p.T138= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as rs750922643, COSV100394491; called by muse, mutect2, varscan2
- DNAH11 | c.9462C>T p.I3154= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs764817397, COSV100179766; ClinVar: likely benign; called by muse, mutect2, varscan2
- DYNC1I1 | c.708G>T p.R236= | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as COSV61467610; called by muse, mutect2, varscan2
- FAT4 | c.12438G>T p.L4146= | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV100629217; called by muse, mutect2, varscan2
- FPR1 | c.555C>T p.N185= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as rs539893573, COSV100494158; called by muse, mutect2
- GFPT2 | c.1116G>C p.V372= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99517669, COSV99517857; called by muse, mutect2
- GFRAL | c.456T>G p.L152= | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV100475475; called by muse, mutect2
- GLT6D1 | c.816C>T p.L272= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100874556; called by muse, mutect2, varscan2
- GRK4 | c.1311C>T p.G437= (on ENST00000398052 / NM_182982.3; = p.G405= on NM_005307.3) | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs745985664, COSV100584145; called by muse, mutect2, varscan2
- HLA-A | c.27C>G p.L9= | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV100954549; called by muse, mutect2, varscan2
- IDS | c.84G>A p.T28= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as rs1194554189, COSV61713199; called by muse, mutect2
- IFNA2 | c.418C>T p.L140= | Silent (SNP) | VAF 28/216 reads (13%) | catalogued as COSV66505355, COSV66505844; called by muse, mutect2, varscan2
- LPA | c.4410G>T p.S1470= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as COSV100307411; called by muse, mutect2, varscan2
- NDP | c.252C>G p.V84= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100955792; called by muse, mutect2, varscan2
- NEB | c.597C>T p.T199= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs762852030, COSV51469007, COSV99425190, COSV99428444; called by muse, mutect2
- NEXMIF | c.3633A>T p.P1211= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as COSV99281201; called by muse, mutect2, varscan2
- NFAT5 | c.1989G>A p.Q663= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100590958; called by muse, mutect2
- NRN1L | c.147C>T p.F49= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs760878086, COSV59304112; called by muse, mutect2, varscan2
- OR51A7 | c.891A>G p.Q297= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs145385072; called by muse, mutect2
- OR5D18 | c.354G>A p.V118= | Silent (SNP) | VAF 32/209 reads (15%) | catalogued as COSV100450764; called by muse, mutect2, varscan2
- OR5M3 | c.765C>T p.F255= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV56566767, COSV56568700; called by muse, mutect2
- OTOP1 | c.810C>T p.L270= | Silent (SNP) | VAF 6/94 reads (6%) | catalogued as COSV99587865; called by muse, mutect2
- OTUD7A | c.849C>T p.S283= (on ENST00000307050 / NM_001382637.1; = p.S276= on NM_130901.3) | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs758269775, COSV61038394; called by muse, mutect2, varscan2
- PEX14 | c.12G>C p.S4= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100750206; called by muse, mutect2
- PKN1 | c.1209G>T p.G403= | Silent (SNP) | VAF 58/312 reads (19%) | catalogued as COSV99661540; called by muse, mutect2, varscan2
- PLPP2 | c.93G>A p.P31= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as rs139859911; called by muse, mutect2, varscan2
- PSMA6 | c.213G>A p.K71= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV54836687, COSV99809231; called by muse, mutect2
- RETNLB | c.51G>A p.L17= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV55465265; called by muse, mutect2, varscan2
- SLCO1B3 | c.516C>A p.I172= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV99681775; called by muse, mutect2, varscan2
- SOHLH2 | c.159G>A p.T53= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs771419979, COSV58521606; called by muse, mutect2, varscan2
- SPG11 | c.618G>A p.T206= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as rs766634102, COSV55992906; called by muse, mutect2, varscan2
- TAOK2 | c.2634G>A p.E878= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV54235582; called by muse, mutect2, varscan2
- TECTA | c.1188C>T p.S396= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as COSV99880499; called by muse, mutect2, varscan2
- TRAJ12 | c.30C>T p.F10= | Silent (SNP) | VAF 7/128 reads (5%) | catalogued as rs1326018607; called by muse, mutect2
- TTPAL | c.228C>T p.L76= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs751998574, COSV99375502; called by muse, mutect2, varscan2
- UBE2Q2 | c.969C>T p.I323= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99143361; called by muse, mutect2, varscan2
- USP32 | c.4311G>A p.Q1437= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV56279978; called by muse, mutect2, varscan2
- ZNF491 | c.1101C>G p.V367= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs1371570401, COSV100021950; called by muse, mutect2, varscan2
- ZNF574 | c.1362G>A p.E454= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99726271; called by muse, mutect2
- GCNT2 | c.925+26950C>G | Intron (SNP) | VAF 14/101 reads (14%) | catalogued as COSV100297312; called by muse, mutect2, varscan2
- NUP214 | c.6075-878C>T | Intron (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- PARGP1 | n.490A>T | RNA (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
